Somatic mutation profile of tumor specimen TCGA-ET-A3BP-01A (aliquot TCGA-ET-A3BP-01A-21D-A19J-08) from TCGA case TCGA-ET-A3BP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 34.5 years (12,594 days).
Specimen TCGA-ET-A3BP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f39db2eb-5ba3-49a3-bd74-f299f5a8990f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3BP-10A (Blood Derived Normal), aliquot TCGA-ET-A3BP-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/858f579c-82b9-4dc7-a238-28ae62b0a4d7

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ADCY7 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs77603243; called by muse, mutect2, varscan2
- KHDRBS2 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760363356, COSV55427189; called by muse, mutect2, varscan2
- MXRA5 | c.1313A>C p.D438A | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV54223809; called by muse, mutect2, varscan2
- ATF7IP2 | c.153G>A p.Q51= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV100202530, COSV61092196; called by muse, mutect2, varscan2
